CCDI case PBCDHN — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Testis.
https://portal.gdc.cancer.gov/cases/2e7c2f8d-6274-4485-bec6-7ec51e4c5f77

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 12.2 years (4,458 days).

Biospecimens (3 samples)
- Sample 0DPBFD: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0DPBFW, 0DPBG4 (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
